Gene-level copy-number profile of tumor specimen TCGA-DX-A8BR-01A from TCGA case TCGA-DX-A8BR, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant fibrous histiocytoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 63.8 years (23,302 days).
Specimen TCGA-DX-A8BR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.413cb162-556c-45d3-a6b5-a8c2462d18be.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A8BR-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 822 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/426c36db-1234-4d89-878b-e9efc98f0267

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 80; copy number 1: 12,178; copy number 2: 42,169; copy number 3: 2,997; copy number 4: 1,534; copy number 5: 128; copy number 6: 388; copy number 7: 197; copy number 8: 81; copy number 11: 44; copy number 12: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A8BR-01A-11D-A416-01): tumor purity 0.69, ploidy 1.91, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 80 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:164,171,471–167,734,939, 30 genes: MIR1263, LINC01323, LINC01324, SI, Y_RNA, LINC02023, SLITRK3, LINC01322, BCHE, MTND4P17, MTND4LP10, MTND3P7, MTCO3P38, MCUR1P2, AC104629.1, LINC01326, AC072046.2, RN7SKP298, PSAT1P4, AC072046.1, CBX1P5, AC069439.2, AC069439.1, PPIAP74, ZBBX, LINC01327, SERPINI2, WDR49, PDCD10, HMGN1P8.
- chr13:48,296,162–49,691,486, 32 genes (within-gene range 0–1): RB1-DT, RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462, CYSLTR2, PSME2P2, AL161421.1, FNDC3A, RNU6-60P, RAD17P2, RNY3P2, COX7CP1, OGFOD1P1, MLNR, AL137000.1, CDADC1, CAB39L, SETDB2, SNRPGP14, PHF11, RCBTB1, AL135901.1, ARL11, EBPL.
- chr13:49,889,634–50,125,720, 13 genes (within-gene range 0–1): RNY4P30, CTAGE10P, RNY4P9, SPRYD7, DLEU2, TRIM13, MIR3613, KCNRG, AL137060.9, AL137060.7, MIR16-1, MIR15A, AL137060.4.
- chr13:50,812,988–51,080,862, 5 genes (within-gene range 0–1): RNA5SP28, RNASEH2B-AS1, RNASEH2B, GUCY1B2, RNA5SP29.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 843 genes in 53 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:146,146,203–148,519,604, 72 genes, copy number 7–11 (within-gene range 3–11) (broad region; genes not listed).
- chr1:165,201,867–165,356,715, 3 genes, copy number 6: LMX1A, LMX1A-AS2, LMX1A-AS1.
- chr1:170,369,223–173,064,015, 56 genes, copy number 6: HAUS4P1, GORAB-AS1, GORAB, AL162399.1, AL023495.1, PRRX1, Z97200.1, BX284613.2, MROH9, BX284613.1, FMO3, MIR1295A, MIR1295B, FMO6P, FMO2, AL021026.1, FMO1, Y_RNA, HMGB1P11, FMO4, TOP1P1, SRP14P4, GM2AP2, CYCSP53, PRRC2C, MYOCOS, MYOC, PFN1P1, RPL4P3, VAMP4, Z98751.1, Z98751.3, Z98751.2, AL135931.1, EEF1AKNMT, AL031864.1, AL031864.2, DNM3, DNM3-IT1, DNM3OS, MIR214, MIR3120, MIR199A2, AL137157.1, RNU6-157P, PIGC, C1orf105, SUCO, RNU6-693P, FASLG, SLC25A38P1, Z98043.1, AL031599.1, AIMP1P2, Z97198.1, TNFSF18.
- chr3:93,843,764–94,507,620, 11 genes, copy number 7: RNU6-488P, PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2, ARMC10P1.
- chr3:109,364,047–109,723,273, 6 genes, copy number 5 (within-gene range 3–5): AC124945.1, AC092905.1, H3P12, LINC01205, PPIAP15, MIR4445.
- chr3:111,570,638–111,976,517, 7 genes, copy number 6 (within-gene range 2–6): AC092916.2, ZBED2, NT5C3AP2, PLCXD2, PLCXD2-AS1, PHLDB2, AC117509.1.
- chr3:112,524,187–115,147,288, 61 genes, copy number 6 (broad region; genes not listed).
- chr3:124,080,023–124,726,325, 5 genes, copy number 7 (within-gene range 2–7): KALRN, MIR5002, RPL7P15, MIR6083, RNU6-143P.
- chr3:127,915,232–128,408,646, 9 genes, copy number 6 (within-gene range 2–6): KBTBD12, RNA5SP139, SEC61A1, RUVBL1, RNU2-37P, RUVBL1-AS1, RNU6-823P, EEFSEC, AL449214.1.
- chr3:139,353,946–139,859,894, 15 genes, copy number 6 (within-gene range 2–6): COPB2, U6, AC046134.2, RBP2, AC097103.1, ACTG1P1, RBP1, NMNAT3, AC046134.1, RN7SKP124, RN7SL724P, AC110716.2, AC110716.1, AC016933.1, TRMT112P5.
- chr3:141,660,536–141,729,405, 3 genes, copy number 6: LINC02618, TPT1P3, AC112771.1.
- chr4:92,303,966–93,830,964, 8 genes, copy number 5 (within-gene range 1–5): GRID2, MTND1P19, AC095059.2, AC095059.1, AC020699.1, AC110800.1, RNA5SP164, ATOH1.
- chr4:108,808,725–110,293,573, 30 genes, copy number 8 (within-gene range 4–8): COL25A1, COL25A1-DT, RBMXP4, SEC24B-AS1, SEC24B, RN7SL55P, MIR576, SETP20, CDC42P4, MCUB, HIGD1AP14, CASP6, AC004067.1, PLA2G12A, AC126283.2, CFI, AC126283.1, GAR1, RRH, LRIT3, KRT19P3, EGF, RNU6-35P, ELOVL6, RN7SL275P, AC093770.1, HSBP1P2, RNF14P2, RNU6-205P, ZBED1P1.
- chr4:110,399,773–110,433,188, 3 genes, copy number 8: RPL7L1P13, ZNF969P, AC093872.1.
- chr4:116,193,997–116,515,619, 6 genes, copy number 5 (within-gene range 1–5): TTC39CP1, MTRNR2L13, MIR1973, TRMT112P1, CUL4AP1, AC106892.1.
- chr4:121,801,318–122,087,811, 7 genes, copy number 8: EXOSC9, CCNA2, BBS7, AC079341.1, TRPC3, AC097533.1, RN7SL335P.
- chr4:131,379,717–132,678,503, 14 genes, copy number 7 (within-gene range 4–7): LINC02377, AC105424.1, RN7SL205P, SNHG27, SNORA70, AC107393.1, RPL7AP28, AC096711.2, AC093916.1, AC096711.1, ELL2P2, AC114741.1, LINC01256, AARS1P1.
- chr4:144,210,701–149,278,123, 75 genes, copy number 6 (within-gene range 1–6) (broad region; genes not listed).
- chr4:155,173,716–159,777,828, 84 genes, copy number 5–7 (broad region; genes not listed).
- chr4:162,521,682–163,473,754, 12 genes, copy number 6: TOMM22P4, AC021134.1, AC021134.2, AC084752.1, MIR4454, AC022272.1, NAF1, AC079238.1, NPY1R, NPY5R, RPL35AP12, TKTL2.
- chr4:165,647,636–167,234,796, 9 genes, copy number 6 (within-gene range 4–6): AC080079.2, AC080079.1, LINC01179, TLL1, RNA5SP170, Y_RNA, AC097487.1, SPOCK3, RNA5SP171.
- chr4:181,064,089–181,591,969, 5 genes, copy number 12: LINC00290, AC019235.1, LINC02500, AC093840.1, AC093840.2.
- chr4:182,548,659–182,917,936, 7 genes, copy number 7: RNU2-34P, RN7SKP67, AC079226.2, AC079226.1, AC114798.1, AC079766.1, DCTD.
- chr7:70,972–989,640, 28 genes, copy number 5: AC093627.1, AC093627.6, AC093627.22, AC093627.5, AC093627.4, AC093627.7, AC093627.2, AC093627.3, FAM20C, AC145676.1, FOXL3, AC188616.1, AC226118.1, AC188617.1, AC188617.2, AC147651.1, PDGFA, HRAT92, PRKAR1B, PRKAR1B-AS2, PRKAR1B-AS1, DNAAF5, SUN1, GET4, AC073957.3, ADAP1, COX19, CYP2W1.
- chr7:2,234,195–2,380,745, 6 genes, copy number 5: MRM2, NUDT1, SNX8, MIR6836, IMMP1LP3, EIF3B.
- chr7:16,970,320–17,467,256, 6 genes, copy number 6 (within-gene range 2–6): AC073332.1, BRWD1P3, Metazoa_SRP, AC019117.3, SNORA63, AC019117.2.
- chr7:25,948,657–26,558,880, 13 genes, copy number 6–8 (within-gene range 4–8): AC010719.1, MIR148A, NFE2L3, HNRNPA2B1, CBX3, AC010677.2, AC010677.1, SNX10, AC004540.2, AC004540.1, KIAA0087, AC004947.2, AC004947.1.
- chr7:27,269,357–28,825,894, 19 genes, copy number 5–8: RPL35P4, HNRNPA1P73, AC004009.1, AC004009.3, AC004009.2, EIF4HP1, PSMC1P2, AC073150.1, HIBADH, AC007130.1, TAX1BP1-AS1, TAX1BP1, JAZF1, AC004549.1, RNU6-979P, JAZF1-AS1, PPIAP80, CREB5, AC005105.1.
- chr7:35,614,650–35,972,587, 11 genes, copy number 8 (within-gene range 3–8): AC018647.3, HERPUD2, AC018647.2, AC018647.1, SEPTIN7-DT, AC007551.1, SEPTIN7, AC007551.2, RNU6-1085P, AC087072.1, SEPTIN7P3.
- chr7:135,092,363–135,648,757, 13 genes, copy number 5 (within-gene range 3–5): CYREN, RNF14P4, TMEM140, AC083862.1, AC083862.2, WDR91, AC009542.1, MIR6509, STRA8, SLC23A4P, CNOT4, SDHDP2, NUP205.
- chr7:140,293,693–140,722,790, 13 genes, copy number 7 (within-gene range 2–7): SLC37A3, RNA5SP247, RNA5SP248, RAB19, AC069335.1, MKRN1, DENND2A, Y_RNA, AC006452.1, RN7SL771P, ADCK2, NDUFB2, NDUFB2-AS1.
- chr7:146,208,665–147,167,572, 5 genes, copy number 5: AC073418.1, Y_RNA, CNTNAP2-AS1, DUTP3, RANP2.
- chr7:148,543,677–150,604,644, 73 genes, copy number 5–7 (broad region; genes not listed).
- chr7:150,824,627–151,144,436, 14 genes, copy number 7 (within-gene range 2–7): AOC1, KCNH2, NOS3, ATG9B, ABCB8, AC010973.1, ASIC3, CDK5, SLC4A2, AC010973.3, AC010973.2, FASTK, TMUB1, AGAP3.
- chr10:44,712–689,668, 13 genes, copy number 5: AL713922.1, TUBB8, IL9RP2, ZMYND11, AL713922.2, RNA5SP297, DIP2C, RNA5SP298, RN7SL754P, AL669841.1, AL358216.1, MIR5699, PRR26.
- chr11:77,514,936–79,441,030, 38 genes, copy number 6–7 (within-gene range 2–7): CLNS1A, RNU7-59P, AQP11, RSF1, Y_RNA, RSF1-IT2, FTH1P16, RSF1-IT1, AP000580.1, AAMDC, AP002812.2, AP002812.3, AP002812.5, AP002812.1, INTS4, AP002812.4, AP003032.2, KCTD14, NDUFC2-KCTD14, AP003032.1, THRSP, NDUFC2, ALG8, RNU6-126P, KCTD21-AS1, KCTD21, USP35, GAB2, AP002985.1, AP003086.1, AP003086.3, AP003086.2, LINC02728, NARS2, AP003110.1, RNU6-311P, COPS8P3, TENM4.
- chr11:79,092,848–79,422,226, 4 genes, copy number 7: AP002957.1, AP001547.1, MIR708, MIR5579.
- chr11:119,065,263–120,185,529, 44 genes, copy number 6: AP003392.4, AP003392.5, VPS11, HMBS, H2AX, DPAGT1, C2CD2L, HINFP, ABCG4, NLRX1, PDZD3, CCDC153, CBL, RNU6-262P, MCAM, MIR6756, AP002956.1, RNF26, AP003396.1, C1QTNF5, MFRP, USP2, USP2-AS1, AP003396.3, AP003396.2, AP003396.4, THY1, THY1-AS1, DUXAP5, KRT8P7, AP003393.1, NECTIN1, RNU6-1123P, NECTIN1-AS1, AP003390.1, AP001994.1, AP001994.2, AP001994.3, AP001360.3, LINC02744, AP001360.1, AP001360.2, TRIM29, AP000679.1.
- chr11:129,815,848–130,041,071, 7 genes, copy number 6: TMEM45B, NFRKB, PRDM10, LINC00167, AP003041.1, ELOBP2, AP003041.2.
- chr13:68,634,190–69,322,190, 8 genes, copy number 5 (within-gene range 1–5): RPS3AP52, RPL12P34, RN7SL761P, LINC00550, LINC02342, ZDHHC20P4, SNRPFP3, LINC00383.

Autosomal genes at a single copy (total copy number 1): 12,077. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
